Somatic mutation profile of tumor specimen TCGA-BQ-7056-01A (aliquot TCGA-BQ-7056-01A-11D-1961-08) from TCGA case TCGA-BQ-7056, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 75.2 years (27,467 days).
Specimen TCGA-BQ-7056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 188fc38a-8aa9-47a5-9812-7ee70669d3b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7056-11A (Solid Tissue Normal), aliquot TCGA-BQ-7056-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/106d81ef-fab8-48c0-b650-dcf73809f09f

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Frame Shift Ins 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.965T>G p.V322G | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV54355565; called by muse, mutect2, varscan2
- ATM | c.8189A>C p.Q2730P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM094663, COSV53748557, COSV53756372, COSV53780029; called by muse, mutect2, varscan2
- DDX4 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768783395, COSV61755195, COSV61757655; called by muse, mutect2, varscan2
- DHX36 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as COSV57673532; called by muse, mutect2, varscan2
- DOCK11 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV52233028, COSV52240284; called by muse, mutect2, varscan2
- DUSP13 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57814816; called by muse, mutect2, varscan2
- FKBP11 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as rs779366277, COSV56739717; called by muse, mutect2, varscan2
- FLG | c.10454C>T p.A3485V | Missense Mutation (SNP) | VAF 141/404 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs200036291; called by muse, mutect2
- HERC1 | c.6122A>G p.Q2041R | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.161); catalogued as COSV71248120; called by muse, mutect2, varscan2
- ODAPH | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756454916, COSV61140864, COSV61141580; called by muse, mutect2, varscan2
- OTOGL | c.719G>A p.G240E (on ENST00000547103; = p.G231E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV72006724; called by muse, mutect2, varscan2
- PCDHGB7 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as COSV53962077; called by muse, mutect2, varscan2
- PHF20L1 | c.1602dup p.V535Sfs*13 | Frame Shift Ins (INS) | VAF 174/306 reads (57%) | catalogued as rs1335277934; called by mutect2, varscan2
- PYCR2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.555); catalogued as COSV100661538, COSV100661546; called by muse, mutect2, varscan2
- RALBP1 | c.1752C>G p.I584M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV50035783; called by muse, mutect2, varscan2
- RANBP10 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV58157576; called by muse, mutect2, varscan2
- RBM15B | c.2191A>T p.S731C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60043360; called by muse, mutect2, varscan2
- TCL1B | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.84); catalogued as rs766566348, COSV61551769, COSV61552059; called by muse, mutect2, varscan2
- TPO | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.127); catalogued as COSV61103221; called by muse, mutect2, varscan2
- TTN | c.62903T>C p.I20968T (on ENST00000591111; = p.I13544T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/176 reads (23%) | PolyPhen benign (0); catalogued as rs778337241, COSV60107922; called by muse, mutect2, varscan2
- UGT2A1 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV54142313; called by muse, mutect2, varscan2
- UGT3A2 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV56931046; called by muse, mutect2, varscan2
- ZNF404 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV60987590; called by muse, mutect2, varscan2
- ZNF578 | c.1262A>C p.H421P | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69736653; called by muse, mutect2
- ALPK3 | c.2040dup p.Q681Tfs*10 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- TARBP2 | c.180dup p.N61* (on ENST00000266987 / NM_134323.2; = p.N40* on NM_004178.4) | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- C11orf1 | c.204C>T p.T68= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV52788896; called by muse, varscan2
- COL7A1 | c.8781C>T p.R2927= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV56476600; called by muse, mutect2, varscan2
- DNAH9 | c.1008G>C p.R336= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV52351874, COSV52353257; called by muse, mutect2, varscan2
- DPYSL4 | c.786C>T p.D262= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs535852329, COSV100633985, COSV58308614; called by mutect2, varscan2
- ZYG11B | c.2130T>C p.H710= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs368928161; called by muse, mutect2, varscan2
- NFAT5 | c.73+2138C>A | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100590960; called by mutect2, varscan2
- TLE3 | c.235-3287G>A | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100450621; called by muse, mutect2, varscan2
